Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACMK, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACMK-TTP1-A (Primary Tumor).

Submissions:

A) lung lobe, removal

TSS verified, (R) lung. *hu***Macroscopic Description****Finding:**

- 1) margin bronchial
- 2) hilum lymph nodes
- 3) neoplasm + pleura
- 4) neoplasm
- 5) lung apex
- 6) residual parenchyma

CDDP-YP-ACMK-01-PR

Lung lobe of cm 15x9x8. To the cut, in the middle third, neoplasia retracting the visceral pleura of cm 3x2.5x2.

Presence of apical calcification.

Macroscopic report and diagnosis:*For TSS, % solid unavailable. hu*

Poorly differentiated adenocarcinoma, G3, with focal areas of solid undifferentiated type (immunohistochemistry reaction to chromogranin is negative). Infiltration of the visceral pleura. Bronchial margin and hilar lymph nodes free of neoplasm. Residue parenchyma with focal chronic emphysema.

ADENOCARCINOMA, G3, pT2 N0 Mx.

ICD-10 Discrepancy		☒
ICD-9 Discrepancy		☒
ICD-10 Malignancy History		☒
ICD-9 Malignancy History		☒

ICD-0-3

adenocarcinoma, NOS 8140/3

Site (R) lung, NOS C34.9

ICD-10

C-34.91

hu
12/16/10

Source: NCI Genomic Data Commons file 05eafe6b-6631-461f-bed9-b379e96729fd (CDDP-ACMK-TTP1.30B5D443-938C-4437-B53E-EC6A5A0614C6.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).